Gene-level copy-number profile of tumor specimen TARGET-51-PALEIR-01A from TARGET case TARGET-51-PALEIR, project TARGET-CCSK (Clear Cell Sarcoma of the Kidney). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell sarcoma of kidney; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 1.3 years (459 days).
Specimen TARGET-51-PALEIR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-CCSK.77b81967-f50f-51df-846d-8156bfb48ecf.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-51-PALEIR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 349 have no estimate.
https://portal.gdc.cancer.gov/files/8777b53e-2227-4c75-8ed9-4c84df910822

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,397; copy number 1: 556; copy number 2: 56,734; copy number 3: 547; copy number 4: 10; copy number 7: 1; copy number 9: 29.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene (within-gene range 0–2): RSRP1.
- chr1:25,266,102–25,362,361, 5 genes (within-gene range 0–2): AL031432.2, RHD, SDHDP6, AL928711.1, TMEM50A.
- chr5:168,706,567–168,720,884, 1 gene: SLIT3-AS2.
- chr13:58,165,827–58,209,483, 1 gene: LINC02338.
- chr17:55,264,960–55,325,187, 1 gene (within-gene range 0–2): HLF.
- chr17:55,325,757–55,327,791, 1 gene: AC007638.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 30 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 9 (within-gene range 2–9): AC244205.1.
- chr2:88,857,161–89,160,366, 28 genes, copy number 9: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21.
- chr14:106,460,092–106,461,055, 1 gene, copy number 7: HOMER2P1.

Autosomal genes at a single copy (total copy number 1): 548. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
